Somatic mutation profile of cancer-model specimen HCM-CSHL-0812-C54-85B (3D Organoid; aliquot HCM-CSHL-0812-C54-85B-01D-A88H-36), derived from the primary tumor of HCMI case HCM-CSHL-0812-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3.
Specimen HCM-CSHL-0812-C54-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3fcd384-485c-41f7-83f8-2f4a3a1c56e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0812-C54-11A (Solid Tissue Normal), aliquot HCM-CSHL-0812-C54-11A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81fcc0d1-9915-419f-a69a-8b47c30ea594

The open-access MAF lists 114 somatic variants for this specimen: 88 protein-altering or splice-affecting, 19 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 19, RNA 4, Intron 3, Nonsense Mutation 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 290/523 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, varscan2
- CCDC88A | c.4730G>A p.G1577E (on ENST00000436346 / NM_001365480.1; = p.G1549E on NM_018084.5) | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.304); catalogued as rs1160306010; called by muse, mutect2, varscan2
- CDHR3 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 278/514 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs765982493, COSV58417555; called by muse, mutect2, varscan2
- CFAP52 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as COSV55347873; called by muse, mutect2
- CHADL | c.1647G>A p.W549* | Nonsense Mutation (SNP) | VAF 159/307 reads (52%) | catalogued as COSV53438026; called by muse, mutect2, varscan2
- CHEK2 | c.574G>A p.E192K (on ENST00000382580 / NM_001005735.2; = p.E149K on NM_007194.4) | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.395); catalogued as rs587782560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLEC14A | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 16/513 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV60561694; called by muse, mutect2
- CUBN | c.9129C>G p.F3043L | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs770481888; called by muse, mutect2
- CYP2E1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 73/262 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs770084630; called by muse, mutect2, varscan2
- DARS2 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.053); catalogued as COSV53407389; called by muse, mutect2, varscan2
- DHCR7 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 296/452 reads (65%) | SIFT tolerated (0.25); PolyPhen benign (0.281); catalogued as rs749913821; called by muse, mutect2, varscan2
- DNAAF3 | c.1003G>A p.E335K (on ENST00000524407 / NM_001256715.2; = p.E382K on NM_178837.4) | Missense Mutation (SNP) | VAF 38/1063 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs1462817124; called by muse, mutect2
- ESX1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 48/652 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV65424139; called by muse, mutect2
- GPATCH8 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 501/502 reads (100%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.997); catalogued as rs779131838; called by muse, varscan2
- GPR158 | c.2782C>T p.R928C | Missense Mutation (SNP) | VAF 105/334 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as rs149419744; called by muse, mutect2, varscan2
- GSX1 | c.571G>C p.V191L | Missense Mutation (SNP) | VAF 11/386 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57232833; called by muse, mutect2
- HSPB8 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 30/701 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs1343984954, COSV56139133; called by muse, mutect2
- ILDR1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 197/460 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs146174741; called by muse, varscan2
- KCTD19 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV58571111; called by muse, mutect2, varscan2
- KIF19 | c.1279G>C p.A427P | Missense Mutation (SNP) | VAF 142/299 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV63429838; called by muse, mutect2, varscan2
- LTF | c.1050G>T p.L350F | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs377433274; called by muse, mutect2, varscan2
- MAGEC2 | c.311G>T p.C104F | Missense Mutation (SNP) | VAF 131/414 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55999672; called by muse, varscan2
- MC2R | c.148T>C p.F50L | Missense Mutation (SNP) | VAF 91/284 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1236638593; called by muse, mutect2, varscan2
- MLLT6 | c.2933G>C p.R978P | Missense Mutation (SNP) | VAF 346/346 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1405440183; called by muse, mutect2, varscan2
- MPDZ | c.4019G>C p.R1340P | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374429110, COSV59916487; called by muse, mutect2, varscan2
- NPR1 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 144/631 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV64143158; called by muse, mutect2, varscan2
- PAPOLG | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs1164822552; called by muse, mutect2, varscan2
- PCDH10 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 202/402 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV52090115; called by muse, mutect2, varscan2
- PDE5A | c.1621C>A p.Q541K | Missense Mutation (SNP) | VAF 26/301 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.052); catalogued as rs760762013; called by muse, mutect2
- PKD1 | c.11098C>T p.R3700C (on ENST00000262304 / NM_001009944.3; = p.R3699C on NM_000296.4) | Missense Mutation (SNP) | VAF 325/325 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs758831274; called by muse, mutect2, varscan2
- PLXNA1 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 119/522 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs769862865, COSV52527647; called by muse, mutect2, varscan2
- RFWD3 | c.1641G>T p.W547C | Missense Mutation (SNP) | VAF 176/486 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746677609; called by mutect2, varscan2
- RMND5B | c.243C>G p.D81E | Missense Mutation (SNP) | VAF 184/386 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.147); catalogued as rs752287259; called by muse, mutect2, varscan2
- RNF151 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 196/392 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as rs374611272; called by muse, mutect2, varscan2
- RRP12 | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 354/534 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs183155457, COSV59669382; called by muse, varscan2
- SEMA4G | c.1398C>A p.H466Q | Missense Mutation (SNP) | VAF 104/349 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52972221; called by muse, mutect2, varscan2
- SPOP | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs1211887878; called by muse, mutect2
- STX1A | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 437/714 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV56096018; called by muse, mutect2, varscan2
- SYT5 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 105/560 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); catalogued as rs1190040113; called by muse, mutect2, varscan2
- TECTA | c.4009G>A p.A1337T | Missense Mutation (SNP) | VAF 271/272 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs373655409; called by muse, mutect2, varscan2
- TENM1 | c.106C>G p.P36A | Missense Mutation (SNP) | VAF 48/499 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100950482; called by muse, mutect2
- TRAV16 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 113/929 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs747312541; called by muse, mutect2, varscan2
- TULP2 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 70/528 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV55477457; called by muse, mutect2, varscan2
- VHLL | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 128/373 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.787); catalogued as rs1431148043; called by muse, mutect2, varscan2
- VPS13B | c.8011C>G p.P2671A | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as COSV62143580; called by muse, mutect2
- ZFYVE28 | c.1892C>G p.S631C | Missense Mutation (SNP) | VAF 143/582 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.751); catalogued as COSV52115410; called by muse, mutect2, varscan2
- ZNF142 | c.1555C>T p.R519C (on ENST00000411696 / NM_001379660.1; = p.R319C on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 142/562 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs201051795; called by muse, mutect2, varscan2
- AC006059.2 | c.1288A>G p.K430E | Missense Mutation (SNP) | VAF 110/364 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- AL713999.2 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 43/982 reads (4%) | called by muse, mutect2
- ARHGEF35 | c.1406T>G p.F469C | Missense Mutation (SNP) | VAF 109/493 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CACNG8 | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- CDC37L1 | c.86T>A p.F29Y | Missense Mutation (SNP) | VAF 36/1418 reads (3%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2
- CTCF | c.1438T>G p.Y480D | Missense Mutation (SNP) | VAF 171/306 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, varscan2
- DENND11 | c.1283A>G p.Q428R | Missense Mutation (SNP) | VAF 44/970 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2
- FAM135B | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM184A | c.1246C>G p.Q416E | Missense Mutation (SNP) | VAF 107/470 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- FAM83C | c.1504A>G p.S502G | Missense Mutation (SNP) | VAF 278/278 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- FCHO1 | c.489G>A p.K163= | Splice Region (SNP) | VAF 83/292 reads (28%) | called by muse, mutect2, varscan2
- GAL3ST1 | c.575A>T p.K192M | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GPD2 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 15/436 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); called by muse, mutect2
- HRNR | c.5342G>C p.G1781A | Missense Mutation (SNP) | VAF 61/1000 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.207); called by muse, varscan2
- INHA | c.368G>T p.S123I | Missense Mutation (SNP) | VAF 40/632 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2
- INPP5F | c.3073T>A p.F1025I | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); called by muse, mutect2
- KCNH1 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KIAA0100 | c.3311C>G p.A1104G | Missense Mutation (SNP) | VAF 220/221 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- LAD1 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 109/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LRTM1 | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 31/501 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); called by muse, mutect2
- MAP3K4 | c.4486C>T p.P1496S | Missense Mutation (SNP) | VAF 79/360 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC12 | c.3571A>C p.I1191L (on ENST00000379442; = p.I1048L on NM_001164462.1) | Missense Mutation (SNP) | VAF 106/148 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by mutect2, varscan2
- NUP155 | c.3359G>T p.R1120L (on ENST00000231498 / NM_153485.3; = p.R1061L on NM_004298.4) | Missense Mutation (SNP) | VAF 51/358 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4S1 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 132/543 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR8A1 | c.325del p.I109Lfs*7 | Frame Shift Del (DEL) | VAF 28/262 reads (11%) | called by mutect2, pindel, varscan2
- PCLO | c.1733A>T p.Q578L | Missense Mutation (SNP) | VAF 83/406 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PDE3A | c.1492G>C p.A498P | Missense Mutation (SNP) | VAF 97/2428 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- RASA1 | c.2920C>T p.L974F | Missense Mutation (SNP) | VAF 102/208 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RELCH | c.2938G>A p.V980M | Missense Mutation (SNP) | VAF 102/275 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIC8A | c.887A>T p.H296L | Missense Mutation (SNP) | VAF 32/677 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2
- RPL39 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCPEP1 | c.1235C>G p.S412C | Missense Mutation (SNP) | VAF 105/765 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- SCPEP1 | c.1291C>A p.H431N | Missense Mutation (SNP) | VAF 48/416 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPATA31D1 | c.2053A>C p.K685Q | Missense Mutation (SNP) | VAF 30/725 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2
- TAOK2 | c.3133C>T p.L1045F | Missense Mutation (SNP) | VAF 22/772 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM255B | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 19/454 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2
- VN1R2 | c.960G>T p.L320F | Missense Mutation (SNP) | VAF 50/491 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WEE2 | c.1385del p.L462Rfs*5 | Frame Shift Del (DEL) | VAF 147/461 reads (32%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.4547A>G p.D1516G | Missense Mutation (SNP) | VAF 100/200 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, varscan2
- ZNF180 | c.519G>T p.L173F | Missense Mutation (SNP) | VAF 69/364 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF865 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 109/939 reads (12%) | SIFT tolerated, low confidence (0.08); called by muse, mutect2, varscan2
- ATP10B | c.3693C>A p.I1231= | Silent (SNP) | VAF 168/399 reads (42%) | called by muse, mutect2, varscan2
- CALCRL | c.1005G>A p.V335= | Silent (SNP) | VAF 93/324 reads (29%) | catalogued as COSV66478454; called by muse, mutect2, varscan2
- CCDC102B | c.759A>G p.E253= | Silent (SNP) | VAF 160/364 reads (44%) | called by muse, mutect2, varscan2
- CDC25C | c.801T>C p.I267= | Silent (SNP) | VAF 23/423 reads (5%) | called by muse, mutect2
- CYP2S1 | c.330T>A p.T110= | Silent (SNP) | VAF 28/275 reads (10%) | called by muse, mutect2, varscan2
- FMO2 | c.423C>T p.D141= | Silent (SNP) | VAF 91/301 reads (30%) | catalogued as rs144325714; called by muse, mutect2, varscan2
- ITPR1 | c.5925C>T p.L1975= (on ENST00000354582; = p.L1920= on NM_002222.7) | Silent (SNP) | VAF 139/344 reads (40%) | catalogued as rs747221954; called by muse, mutect2, varscan2
- L3MBTL1 | c.1188C>G p.P396= (on ENST00000418998 / NM_001377303.1; = p.P306= on NM_015478.7) | Silent (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- METAP1 | c.54C>T p.A18= | Silent (SNP) | VAF 21/553 reads (4%) | catalogued as rs1175819869; called by muse, mutect2
- OR4L1 | c.567C>T p.C189= | Silent (SNP) | VAF 132/530 reads (25%) | called by muse, mutect2, varscan2
- PPP1R3F | c.390C>A p.R130= | Silent (SNP) | VAF 32/525 reads (6%) | called by muse, mutect2
- RNF222 | c.78C>T p.G26= | Silent (SNP) | VAF 302/302 reads (100%) | catalogued as rs562199310, COSV59730825; called by muse, mutect2, varscan2
- SGSM1 | c.2730T>A p.S910= (on ENST00000400359 / NM_001039948.4; = p.S849= on NM_133454.3) | Silent (SNP) | VAF 104/236 reads (44%) | called by muse, mutect2, varscan2
- SLITRK5 | c.99C>T p.L33= | Silent (SNP) | VAF 110/236 reads (47%) | catalogued as rs755181402, COSV61522913; called by muse, mutect2, varscan2
- TASOR2 | c.876C>T p.D292= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as rs200764347, COSV60169858; called by muse, mutect2, varscan2
- TMEM151B | c.1128C>T p.H376= | Silent (SNP) | VAF 26/886 reads (3%) | called by muse, mutect2
- TMEM39A | c.1308C>G p.L436= | Silent (SNP) | VAF 175/350 reads (50%) | catalogued as rs758710970; called by muse, mutect2, varscan2
- WDFY3 | c.201G>A p.P67= | Silent (SNP) | VAF 57/219 reads (26%) | catalogued as rs552529188; called by muse, mutect2, varscan2
- ZNF449 | c.180G>A p.K60= | Silent (SNP) | VAF 19/696 reads (3%) | catalogued as rs1556448648; called by muse, mutect2
- AL390726.5 | n.561C>T | RNA (SNP) | VAF 30/686 reads (4%) | called by muse, mutect2
- ASIC1 | c.559-3166C>T | Intron (SNP) | VAF 148/611 reads (24%) | called by muse, mutect2, varscan2
- DCHS2 | n.2021G>A | RNA (SNP) | VAF 144/344 reads (42%) | called by muse, varscan2
- NEK10 | c.3010+11C>A | Intron (SNP) | VAF 32/178 reads (18%) | called by muse, mutect2, varscan2
- SLC25A1P5 | n.243G>A | RNA (SNP) | VAF 166/5148 reads (3%) | catalogued as rs542439297; called by muse, mutect2
- TLR8 | c.3+3708G>A | Intron (SNP) | VAF 118/275 reads (43%) | catalogued as COSV54320449; called by muse, mutect2, varscan2
- Z99774.4 | n.38G>A | RNA (SNP) | VAF 17/247 reads (7%) | catalogued as rs1367752973; called by muse, mutect2
